TCGA case TCGA-10-0933 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9446e349-71e6-455a-aa8f-53ec96597146

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Dead; Days to death: 446 days (1.2 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 77.8 years (28,433 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Initial disease status: Recurrent Disease; Days to treatment start: 20 days; Days to treatment end: 132 days; Number of cycles: 6; Treatment dose: 2,160 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Recurrent Disease; Days to treatment start: 20 days; Days to treatment end: 132 days; Number of cycles: 6; Treatment dose: 1,740 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 78.8 years (28,789 days); Days to diagnosis: 356 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 356 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 356 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 446 days (1.2 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-10-0933-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-10-0933-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-10-0933-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-10-0933-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Adjuvant and Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Adjuvant and Recurrence.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 446 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 446 days; disease-free interval: event (new tumor event after initially disease-free), 356 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 356 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-10-0933-01A-01D-0399-01): tumor purity 0.91, ploidy 2.62, whole-genome doublings 1.
